Somatic mutation profile of tumor specimen ALCH-B1JA-TTP1-A (aliquot ALCH-B1JA-TTP1-A-1-0-D-A714-36) from ALCHEMIST case ALCH-B1JA, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.7 years (22,534 days).
Specimen ALCH-B1JA-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 10fbb729-30e0-435f-ad9d-f5422969c7a5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1JA-NB1-A (Blood Derived Normal), aliquot ALCH-B1JA-NB1-A-1-0-D-A714-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e6ac58b5-385e-4971-b0d6-ca1e91c491bf

The open-access MAF lists 466 somatic variants for this specimen: 318 protein-altering or splice-affecting, 92 silent, 56 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 274, Silent 92, Intron 26, Nonsense Mutation 23, RNA 12, 3'UTR 9, Splice Site 9, Splice Region 8, Frame Shift Del 3, 5'Flank 3, 3'Flank 3, 5'UTR 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 12/258 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99710992; called by muse, mutect2
- AGPS | c.1957G>A p.G653R | Missense Mutation (SNP) | VAF 31/622 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51560875; called by muse, mutect2
- ANGPT1 | c.660A>T p.Q220H | Missense Mutation (SNP) | VAF 24/558 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV52439307; called by muse, mutect2
- ANKRD34B | c.1327C>T p.Q443* | Nonsense Mutation (SNP) | VAF 18/197 reads (9%) | catalogued as rs1008270083, COSV100103605; called by muse, mutect2
- ANO4 | c.2112G>A p.M704I (on ENST00000392977 / NM_001286615.2; = p.M669I on NM_178826.4) | Missense Mutation (SNP) | VAF 17/255 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV54592706; called by muse, mutect2
- AOAH | c.703-1G>T p.X235_splice | Splice Site (SNP) | VAF 22/335 reads (7%) | catalogued as rs1194597825; called by muse, mutect2
- AR | c.1768G>C p.G590R | Missense Mutation (SNP) | VAF 39/310 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101017463; called by muse, mutect2, varscan2
- ARSH | c.216G>T p.G72= | Splice Region (SNP) | VAF 10/126 reads (8%) | catalogued as COSV66962461; called by muse, mutect2
- ASTN1 | c.2673C>A p.G891= | Splice Region (SNP) | VAF 21/240 reads (9%) | catalogued as COSV100706214; called by muse, mutect2
- ASXL1 | c.2938A>T p.I980F | Missense Mutation (SNP) | VAF 22/397 reads (6%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.056); catalogued as COSV60124932; called by muse, mutect2
- ATR | c.7067G>T p.R2356L | Missense Mutation (SNP) | VAF 26/292 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as COSV63385384; called by muse, mutect2
- BCHE | c.1737C>A p.N579K | Missense Mutation (SNP) | VAF 32/471 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs764962053; called by muse, mutect2
- C11orf87 | c.239C>G p.S80C | Missense Mutation (SNP) | VAF 31/380 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as rs1237174441, COSV59357410; called by muse, mutect2
- C4orf50 | c.52G>T p.A18S (on ENST00000324058; = p.A1250S on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as rs1269760499; called by muse, mutect2
- CACNA1I | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 78/331 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100361573; called by muse, mutect2, varscan2
- CACNG3 | c.296-1G>T p.X99_splice | Splice Site (SNP) | VAF 7/73 reads (10%) | catalogued as COSV99135398; called by muse, varscan2
- CASP4 | c.976C>T p.L326F | Missense Mutation (SNP) | VAF 24/306 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs1421096493; called by muse, mutect2
- CCL20 | c.115C>A p.R39S | Missense Mutation (SNP) | VAF 29/279 reads (10%) | SIFT tolerated (0.87); PolyPhen benign (0.025); catalogued as COSV62591181; called by muse, mutect2, varscan2
- CDH5 | c.2263G>T p.V755L | Missense Mutation (SNP) | VAF 41/355 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV58516036; called by muse, mutect2, varscan2
- CENPE | c.5353G>C p.E1785Q | Missense Mutation (SNP) | VAF 31/464 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); catalogued as COSV54378601, COSV54389100; called by muse, mutect2
- CHRNB4 | c.295G>T p.G99C | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55715963; called by muse, mutect2
- CIB3 | c.410G>C p.R137P | Missense Mutation (SNP) | VAF 56/293 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.922); catalogued as rs112299653, COSV54165420, COSV54166004, COSV99521830; called by muse, mutect2, varscan2
- COL11A1 | c.1307C>T p.P436L | Missense Mutation (SNP) | VAF 20/457 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100617853; called by muse, mutect2
- CREB3L3 | c.329C>A p.P110H | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.339); catalogued as COSV50229695; called by muse, mutect2, varscan2
- CSMD1 | c.6315C>G p.S2105R (on ENST00000520002; = p.S2104R on NM_033225.6) | Missense Mutation (SNP) | VAF 30/371 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV59339100, COSV59377096; called by muse, mutect2
- CSMD3 | c.1286C>A p.P429Q | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.991); catalogued as rs535411359, COSV99823742, COSV99828848; called by muse, mutect2
- DAGLA | c.2818G>T p.E940* | Nonsense Mutation (SNP) | VAF 34/319 reads (11%) | catalogued as COSV99944739; called by muse, mutect2, varscan2
- DNAJC21 | c.856A>T p.N286Y | Missense Mutation (SNP) | VAF 42/383 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as COSV100331284; called by muse, mutect2, varscan2
- EBF2 | c.1291G>T p.G431C | Missense Mutation (SNP) | VAF 20/381 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.832); catalogued as COSV101282150, COSV68776041; called by muse, mutect2
- ENPP2 | c.934G>T p.D312Y | Missense Mutation (SNP) | VAF 22/427 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs866504624; called by muse, mutect2
- ERBB4 | c.2405G>T p.G802V | Missense Mutation (SNP) | VAF 41/319 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61483119; called by muse, mutect2, varscan2
- F5 | c.3682C>A p.Q1228K | Missense Mutation (SNP) | VAF 56/510 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as COSV100889060; called by muse, varscan2
- FAM120C | c.553C>A p.R185S | Missense Mutation (SNP) | VAF 11/284 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.545); catalogued as COSV60260245; called by muse, mutect2
- GATA3 | c.572C>A p.P191H | Missense Mutation (SNP) | VAF 20/462 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as COSV60520695; called by muse, mutect2
- H3-3A | c.295G>T p.A99S | Missense Mutation (SNP) | VAF 27/334 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); catalogued as COSV64732514; called by muse, mutect2
- HAS2 | c.1273A>T p.S425C | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV58265821; called by muse, mutect2, varscan2
- HIVEP3 | c.6299G>T p.G2100V | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV56015610; called by muse, varscan2
- ICAM2 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 29/209 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs763561197; called by muse, mutect2, varscan2
- IGHV2-70 | c.188G>T p.G63V | Missense Mutation (SNP) | VAF 31/336 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs556768737; called by muse, mutect2
- IGKV3-20 | c.193C>G p.P65A | Missense Mutation (SNP) | VAF 35/689 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs921893458; called by muse, mutect2
- IRF4 | c.244C>T p.R82* | Nonsense Mutation (SNP) | VAF 22/141 reads (16%) | catalogued as rs1302327519, COSV66704534; called by muse, mutect2, varscan2
- JUP | c.1238G>C p.G413A | Missense Mutation (SNP) | VAF 13/200 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV60278177; called by muse, mutect2
- KEAP1 | c.779G>C p.R260P | Missense Mutation (SNP) | VAF 22/238 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50281488, COSV50317507; called by muse, mutect2
- KLHL40 | c.1718G>T p.G573V | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV55137011; called by muse, mutect2, varscan2
- KRT34 | c.164G>T p.R55L | Missense Mutation (SNP) | VAF 40/352 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.124); catalogued as rs139913573, COSV101222525; called by muse, mutect2, varscan2
- LAMA5 | c.10694G>A p.R3565Q | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756286327; called by muse, mutect2, varscan2
- LDHAL6B | c.251G>A p.C84Y | Missense Mutation (SNP) | VAF 37/400 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs763817325; called by muse, mutect2
- MGAT5B | c.817G>T p.A273S | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs1248980317; called by muse, mutect2, varscan2
- MROH2B | c.1567G>T p.G523W | Missense Mutation (SNP) | VAF 28/266 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101270427; called by muse, mutect2
- MUC16 | c.948G>T p.E316D | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as COSV67471841; called by muse, mutect2, varscan2
- MYOM3 | c.3857C>G p.S1286* | Nonsense Mutation (SNP) | VAF 18/324 reads (6%) | catalogued as COSV58401179; called by muse, mutect2
- NEK6 | c.32G>C p.G11A | Missense Mutation (SNP) | VAF 13/269 reads (5%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.185); catalogued as COSV57220291; called by muse, mutect2
- NLRP1 | c.373C>A p.P125T | Missense Mutation (SNP) | VAF 30/277 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV52558243; called by muse, mutect2, varscan2
- ODC1 | c.1193A>G p.N398S | Missense Mutation (SNP) | VAF 34/489 reads (7%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.926); catalogued as rs767798988; called by muse, mutect2
- OR1C1 | c.380G>T p.C127F | Missense Mutation (SNP) | VAF 15/171 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV68715475; called by muse, mutect2
- OR52N1 | c.199C>G p.L67V | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as COSV100398626; called by muse, mutect2
- OR5T3 | c.48G>C p.K16N | Missense Mutation (SNP) | VAF 28/346 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as COSV57379570, COSV57379977; called by muse, mutect2
- OR8K5 | c.811G>C p.D271H | Missense Mutation (SNP) | VAF 26/332 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV57887868, COSV57888064, COSV57888107; called by muse, mutect2
- PAK5 | c.330G>T p.Q110H | Missense Mutation (SNP) | VAF 20/368 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.254); catalogued as COSV100781116; called by muse, mutect2
- PCDHA8 | c.1721G>A p.G574D | Missense Mutation (SNP) | VAF 16/340 reads (5%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.031); catalogued as rs1265015709; called by muse, mutect2
- PCDHB14 | c.1400C>A p.A467D | Missense Mutation (SNP) | VAF 45/908 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as rs782059763; called by muse, mutect2
- PCDHB6 | c.1946C>T p.P649L | Missense Mutation (SNP) | VAF 24/378 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.273); catalogued as COSV99169938; called by muse, mutect2
- PDGFRA | c.991G>T p.E331* | Nonsense Mutation (SNP) | VAF 17/183 reads (9%) | catalogued as COSV57264594, COSV57271693; called by muse, mutect2
- PEG3 | c.4202C>T p.A1401V | Missense Mutation (SNP) | VAF 54/303 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.127); catalogued as COSV55642892; called by muse, varscan2
- PIEZO2 | c.1868A>G p.E623G | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1305329239; called by muse, mutect2
- PLAAT1 | c.466G>T p.A156S (on ENST00000650797; = p.A51S on NM_020386.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as COSV99066884; called by muse, mutect2
- PLCB4 | c.3169G>T p.A1057S | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV53806095; called by muse, mutect2
- PRDM9 | c.1634C>A p.T545K | Missense Mutation (SNP) | VAF 44/572 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as COSV57013759, COSV57015243; called by muse, mutect2
- RB1CC1 | c.79G>T p.D27Y | Missense Mutation (SNP) | VAF 12/159 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99073508; called by muse, mutect2
- RIBC1 | c.903G>T p.Q301H | Missense Mutation (SNP) | VAF 15/276 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs1293253173; called by muse, mutect2
- RPA4 | c.607G>T p.D203Y | Missense Mutation (SNP) | VAF 30/513 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.269); catalogued as COSV100232776; called by muse, mutect2
- RYR2 | c.13512G>C p.M4504I | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.041); catalogued as HM030022; called by muse, mutect2
- SCAF8 | c.2083C>T p.P695S | Missense Mutation (SNP) | VAF 29/555 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); catalogued as rs948377077; called by muse, mutect2
- SCN1A | c.1187G>T p.G396V | Missense Mutation (SNP) | VAF 16/278 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as CM117666, COSV100320726; called by muse, mutect2
- SEPTIN4 | c.1162G>C p.G388R | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.414); catalogued as COSV58729081; called by muse, mutect2, varscan2
- SI | c.2339T>C p.M780T | Missense Mutation (SNP) | VAF 36/540 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as rs1181559084; called by muse, mutect2
- SLC43A2 | c.1351-3C>T | Splice Region (SNP) | VAF 12/122 reads (10%) | catalogued as rs905733784; called by muse, mutect2, varscan2
- SLC8B1 | c.1136A>G p.Y379C | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs749390715; called by muse, mutect2, varscan2
- SLC9A4 | c.295G>C p.E99Q | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV54832383; called by muse, mutect2
- SLITRK1 | c.608G>T p.G203V | Missense Mutation (SNP) | VAF 55/512 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); catalogued as COSV65678049; called by muse, mutect2, varscan2
- TAAR6 | c.278C>A p.T93K | Missense Mutation (SNP) | VAF 26/494 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV51583101; called by muse, mutect2
- TBC1D4 | c.3498G>C p.M1166I | Missense Mutation (SNP) | VAF 31/504 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.35); catalogued as rs753086826; called by muse, mutect2
- TBX22 | c.1552C>A p.H518N | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.018); catalogued as COSV64788028; called by muse, mutect2
- TLE1 | c.2126G>C p.C709S | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.163); catalogued as COSV100918912; called by muse, mutect2
- TMEM132D | c.1775G>A p.G592E | Missense Mutation (SNP) | VAF 27/312 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.755); catalogued as rs759077899, COSV101243019; called by muse, mutect2
- TMEM132E | c.1717C>T p.P573S (on ENST00000321639; = p.P663S on NM_001304438.2) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs895738712; called by muse, varscan2
- TSPAN8 | c.275T>G p.L92W | Missense Mutation (SNP) | VAF 29/231 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762533629; called by muse, mutect2, varscan2
- TTN | c.48764G>A p.G16255E (on ENST00000591111; = p.G8831E on NM_003319.4) | Missense Mutation (SNP) | VAF 21/177 reads (12%) | PolyPhen probably damaging (1); catalogued as COSV59889077, COSV59992083; called by muse, mutect2, varscan2
- TTN | c.44517C>A p.S14839R (on ENST00000591111; = p.S7415R on NM_003319.4) | Missense Mutation (SNP) | VAF 6/126 reads (5%) | PolyPhen probably damaging (0.997); catalogued as COSV59969708; called by muse, mutect2
- UBQLN1 | c.821G>T p.R274L | Missense Mutation (SNP) | VAF 19/269 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV57407633; called by muse, mutect2
- UNC5C | c.561G>T p.Q187H | Missense Mutation (SNP) | VAF 46/429 reads (11%) | SIFT tolerated (0.88); PolyPhen possibly damaging (0.522); catalogued as COSV71662935; called by muse, mutect2, varscan2
- WNT4 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 23/447 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.083); catalogued as rs929237108; called by muse, mutect2
- ZFHX3 | c.627G>C p.E209D | Missense Mutation (SNP) | VAF 23/188 reads (12%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.791); catalogued as COSV51708074, COSV99214181; called by muse, mutect2, varscan2
- ZNF436 | c.259G>T p.E87* | Nonsense Mutation (SNP) | VAF 14/374 reads (4%) | catalogued as COSV58358161; called by muse, mutect2
- ZNF454 | c.530C>G p.A177G | Missense Mutation (SNP) | VAF 22/299 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.039); catalogued as COSV60766905, COSV60767820; called by muse, mutect2
- ZNF99 | c.872G>A p.G291D | Missense Mutation (SNP) | VAF 25/231 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.737); catalogued as rs1304482876, COSV68055495; called by muse, mutect2, varscan2
- AADAT | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); called by muse, mutect2
- ABCA13 | c.14602G>T p.A4868S | Missense Mutation (SNP) | VAF 10/242 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- ABCF3 | c.700A>C p.I234L | Missense Mutation (SNP) | VAF 32/340 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.05); called by muse, mutect2
- ACACB | c.6675G>T p.R2225S | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- ACTRT2 | c.135G>T p.Q45H | Missense Mutation (SNP) | VAF 16/267 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.521); called by muse, mutect2
- ACVR2A | c.524C>T p.T175I | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2
- ADCY2 | c.2536G>A p.E846K | Missense Mutation (SNP) | VAF 45/356 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRB1 | c.2076C>A p.N692K | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- AFAP1L1 | c.607C>T p.Q203* | Nonsense Mutation (SNP) | VAF 54/391 reads (14%) | called by muse, mutect2, varscan2
- AGRN | c.4570G>T p.D1524Y | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- AKR7A3 | c.711G>T p.W237C | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AL713999.2 | c.596C>A p.P199Q | Missense Mutation (SNP) | VAF 20/278 reads (7%) | called by muse, mutect2
- ALAS2 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.026); called by muse, mutect2
- AMPH | c.1427C>G p.A476G | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.075); called by muse, mutect2
- ANK2 | c.1062C>A p.H354Q | Missense Mutation (SNP) | VAF 38/643 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2
- ANKRD62 | c.2708G>C p.R903T | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2
- ANO1 | c.2137T>A p.Y713N | Missense Mutation (SNP) | VAF 32/345 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); called by muse, mutect2
- ANP32E | c.755G>T p.G252V | Missense Mutation (SNP) | VAF 43/395 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- APOBEC3B | c.177G>T p.V59= | Splice Region (SNP) | VAF 5/66 reads (8%) | called by muse, mutect2
- ARFGEF1 | c.3094G>T p.V1032L | Missense Mutation (SNP) | VAF 27/310 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.251); called by muse, mutect2
- ARSI | c.1389G>T p.W463C | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- ASB13 | c.644G>T p.G215V | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ATP10A | c.2020G>T p.A674S | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (0.84); PolyPhen benign (0.01); called by muse, mutect2
- ATP11A | c.2884T>A p.W962R | Missense Mutation (SNP) | VAF 15/364 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.067); called by muse, mutect2
- AVPR1B | c.118G>A p.V40I | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.163); called by muse, mutect2
- C12orf66 | c.724G>T p.G242* | Nonsense Mutation (SNP) | VAF 19/221 reads (9%) | called by muse, mutect2
- C3orf20 | c.746G>T p.G249V | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- CABLES2 | c.968T>A p.I323N | Missense Mutation (SNP) | VAF 10/181 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.186); called by muse, mutect2
- CACNA1B | c.3407C>A p.T1136N | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- CACNA1G | c.3420G>T p.Q1140H | Missense Mutation (SNP) | VAF 26/368 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.396); called by muse, mutect2
- CACNG3 | c.296-2A>T p.X99_splice | Splice Site (SNP) | VAF 7/69 reads (10%) | called by muse, varscan2
- CAPN14 | c.1354G>C p.D452H | Missense Mutation (SNP) | VAF 19/436 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.386); called by muse, mutect2
- CBLL1 | c.547C>G p.Q183E | Missense Mutation (SNP) | VAF 42/496 reads (8%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.954); called by muse, mutect2
- CCDC154 | c.772G>T p.E258* | Nonsense Mutation (SNP) | VAF 10/88 reads (11%) | called by muse, mutect2, varscan2
- CCDC54 | c.643C>A p.P215T | Missense Mutation (SNP) | VAF 24/310 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.031); called by muse, mutect2
- CCDC88C | c.3962G>T p.C1321F | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2
- CDC42BPB | c.2407G>T p.D803Y | Missense Mutation (SNP) | VAF 19/179 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- CDH26 | c.1612T>A p.L538M | Missense Mutation (SNP) | VAF 21/304 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- CEMIP | c.1330A>G p.T444A | Missense Mutation (SNP) | VAF 33/240 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- CENPF | c.9116C>A p.T3039K | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- CFAP44 | c.2137G>T p.E713* | Nonsense Mutation (SNP) | VAF 32/504 reads (6%) | called by muse, mutect2
- CFAP54 | c.3184del p.S1062Afs*3 | Frame Shift Del (DEL) | VAF 43/277 reads (16%) | called by mutect2, pindel, varscan2
- CHD2 | c.3306G>C p.E1102D | Missense Mutation (SNP) | VAF 24/209 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CHRNA10 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 10/185 reads (5%) | SIFT tolerated (0.86); PolyPhen benign (0.02); called by muse, mutect2
- CIB4 | c.259G>A p.G87S | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, mutect2
- CLASP1 | c.2428A>T p.K810* | Nonsense Mutation (SNP) | VAF 12/102 reads (12%) | called by muse, mutect2, varscan2
- CLCN1 | c.1177T>A p.Y393N | Missense Mutation (SNP) | VAF 24/668 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CLCN2 | c.220G>T p.V74F | Missense Mutation (SNP) | VAF 22/354 reads (6%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2
- CLUH | c.133G>T p.D45Y (on ENST00000435359; = p.D83Y on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/219 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- CNTNAP2 | c.1812C>A p.H604Q | Missense Mutation (SNP) | VAF 29/581 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.082); called by muse, mutect2
- COL11A1 | c.1306C>A p.P436T | Missense Mutation (SNP) | VAF 20/461 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL21A1 | c.1597-2A>G p.X533_splice | Splice Site (SNP) | VAF 20/256 reads (8%) | called by muse, mutect2
- COL24A1 | c.772_778del p.T258Yfs*35 | Frame Shift Del (DEL) | VAF 19/125 reads (15%) | called by mutect2, pindel, varscan2
- COL3A1 | c.1870G>T p.G624W | Missense Mutation (SNP) | VAF 23/358 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CPA6 | c.770G>C p.R257T | Missense Mutation (SNP) | VAF 34/364 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2
- CR1 | c.3199G>T p.G1067W | Missense Mutation (SNP) | VAF 36/480 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2
- CR1 | c.5243G>T p.R1748M | Missense Mutation (SNP) | VAF 36/378 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.847); called by muse, mutect2
- CRHR1 | c.310G>T p.E104* | Nonsense Mutation (SNP) | VAF 31/261 reads (12%) | called by muse, mutect2, varscan2
- CSAD | c.519G>T p.Q173H (on ENST00000444623 / NM_001244705.2; = p.Q200H on NM_015989.5) | Missense Mutation (SNP) | VAF 55/358 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- CTTNBP2 | c.491G>T p.R164L | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- CWF19L2 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 31/491 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.251); called by muse, mutect2
- DDX60L | c.3085G>T p.E1029* | Nonsense Mutation (SNP) | VAF 12/220 reads (5%) | called by muse, mutect2
- DENND4B | c.1058A>T p.H353L | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- DGKI | c.2484G>T p.W828C | Missense Mutation (SNP) | VAF 22/228 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- DLGAP3 | c.1156G>T p.E386* | Nonsense Mutation (SNP) | VAF 37/268 reads (14%) | called by muse, mutect2, varscan2
- DOCK2 | c.122G>T p.C41F | Missense Mutation (SNP) | VAF 26/259 reads (10%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DPP10 | c.13G>T p.A5S | Missense Mutation (SNP) | VAF 22/512 reads (4%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.956); called by muse, mutect2
- DPP6 | c.14C>A p.A5D | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- DTNB | c.1342A>T p.R448* | Nonsense Mutation (SNP) | VAF 13/204 reads (6%) | called by muse, mutect2
- EEA1 | c.1489C>T p.Q497* | Nonsense Mutation (SNP) | VAF 89/590 reads (15%) | called by muse, mutect2, varscan2
- EML5 | c.4306C>A p.Q1436K (on ENST00000380664; = p.Q1444K on NM_183387.3) | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- ENG | c.1697G>A p.R566K | Missense Mutation (SNP) | VAF 78/469 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EPB41L3 | c.2609C>A p.A870D | Missense Mutation (SNP) | VAF 18/446 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.224); called by muse, mutect2
- ERN2 | c.1899A>T p.I633= | Splice Region (SNP) | VAF 18/154 reads (12%) | called by muse, mutect2, varscan2
- FAM120C | c.3157C>A p.P1053T | Missense Mutation (SNP) | VAF 10/230 reads (4%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.01); called by muse, mutect2
- FAM168B | c.32G>T p.G11V | Missense Mutation (SNP) | VAF 28/257 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- FAM169A | c.1211G>T p.R404L | Missense Mutation (SNP) | VAF 12/356 reads (3%) | SIFT tolerated (0.35); PolyPhen benign (0.272); called by muse, mutect2
- FIG4 | c.841G>T p.G281C | Missense Mutation (SNP) | VAF 33/585 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FOXP2 | c.125C>A p.S42Y | Missense Mutation (SNP) | VAF 25/311 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- FRMPD1 | c.4279G>T p.E1427* | Nonsense Mutation (SNP) | VAF 28/193 reads (15%) | called by muse, mutect2, varscan2
- FSIP2 | c.10814A>T p.Q3605L | Missense Mutation (SNP) | VAF 20/402 reads (5%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2
- GAP43 | c.677G>A p.G226D | Missense Mutation (SNP) | VAF 14/269 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.241); called by muse, mutect2
- GLI2 | c.1564G>T p.G522C (on ENST00000361492 / NM_001374353.1; = p.G539C on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/147 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GNS | c.1123G>T p.G375C | Missense Mutation (SNP) | VAF 72/487 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- GOLGB1 | c.4873G>A p.V1625I | Missense Mutation (SNP) | VAF 26/408 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.717); called by muse, mutect2
- GRIN3A | c.1840A>T p.T614S | Missense Mutation (SNP) | VAF 32/718 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.662); called by muse, mutect2
- GSE1 | c.2771A>T p.Q924L | Missense Mutation (SNP) | VAF 35/352 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- GSTA3 | c.281T>A p.M94K | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); called by muse, mutect2
- GZMH | c.195C>A p.C65* | Nonsense Mutation (SNP) | VAF 12/174 reads (7%) | called by muse, mutect2
- HACD3 | c.337G>T p.E113* | Nonsense Mutation (SNP) | VAF 10/102 reads (10%) | called by muse, mutect2
- HACE1 | c.1366A>T p.I456F | Missense Mutation (SNP) | VAF 16/292 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.36); called by muse, mutect2
- HERC1 | c.9389C>T p.A3130V | Missense Mutation (SNP) | VAF 36/362 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.978); called by muse, mutect2
- HERC1 | c.4099G>A p.E1367K | Missense Mutation (SNP) | VAF 36/304 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- HRH3 | c.418-2A>C p.X140_splice | Splice Site (SNP) | VAF 3/20 reads (15%) | called by muse, mutect2
- HTR3D | c.331G>T p.G111C (on ENST00000382489 / NM_001163646.2; = p.G50C on NM_001145143.1) | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- IMPA1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 26/348 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- INSYN2B | c.1450G>T p.G484C | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- INTS8 | c.1298A>T p.E433V | Missense Mutation (SNP) | VAF 16/276 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.24); called by muse, mutect2
- ITCH | c.2155G>T p.D719Y (on ENST00000262650 / NM_001257137.3; = p.D678Y on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/397 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- ITGAL | c.3126G>C p.E1042D | Missense Mutation (SNP) | VAF 28/247 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ITIH6 | c.1813C>A p.L605M | Missense Mutation (SNP) | VAF 23/615 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); called by muse, mutect2
- ITPR2 | c.5927A>G p.Y1976C | Missense Mutation (SNP) | VAF 64/573 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITPR3 | c.6140G>T p.R2047L | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- KCP | c.3019C>A p.Q1007K (on ENST00000620378; = p.Q1067K on NM_001366122.1) | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- KIAA0319L | c.1051C>G p.H351D | Missense Mutation (SNP) | VAF 30/348 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2
- KIF4B | c.1757A>G p.K586R | Missense Mutation (SNP) | VAF 25/421 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); called by muse, mutect2
- KYAT3 | c.955-1G>T p.X319_splice | Splice Site (SNP) | VAF 7/56 reads (13%) | called by muse, mutect2
- LAMA2 | c.5562+1G>C p.X1854_splice | Splice Site (SNP) | VAF 28/465 reads (6%) | called by muse, mutect2
- LAMA3 | c.9670G>A p.G3224S (on ENST00000313654 / NM_198129.4; = p.G1615S on NM_000227.6) | Missense Mutation (SNP) | VAF 24/562 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.426); called by muse, mutect2
- LINC02740 | n.335-1G>T | Splice Site (SNP) | VAF 36/329 reads (11%) | called by muse, mutect2, varscan2
- LINGO1 | c.1438G>T p.G480C | Missense Mutation (SNP) | VAF 9/237 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LLGL2 | c.2172G>T p.K724N | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MBOAT1 | c.1333G>A p.A445T | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.784); called by muse, mutect2
- MEDAG | c.185A>T p.E62V | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.135); called by mutect2, varscan2
- MMP16 | c.1565C>A p.P522Q | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MRGPRD | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- MTR | c.2816G>T p.G939V | Missense Mutation (SNP) | VAF 53/502 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2
- MTUS2 | c.97G>T p.G33* | Nonsense Mutation (SNP) | VAF 14/380 reads (4%) | called by muse, mutect2
- MXRA5 | c.7692C>G p.C2564W | Missense Mutation (SNP) | VAF 39/525 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MYH2 | c.4771C>G p.Q1591E | Missense Mutation (SNP) | VAF 20/506 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.396); called by muse, mutect2
- MYH2 | c.4770C>A p.D1590E | Missense Mutation (SNP) | VAF 20/501 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- MYO18B | c.3951+1G>T p.X1317_splice | Splice Site (SNP) | VAF 12/195 reads (6%) | called by muse, mutect2
- NAGPA | c.1222T>A p.C408S | Missense Mutation (SNP) | VAF 36/352 reads (10%) | PolyPhen probably damaging (0.998); called by muse, mutect2
- NDC1 | c.1072C>A p.H358N | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by mutect2, varscan2
- NDST3 | c.1068A>T p.T356= | Splice Region (SNP) | VAF 15/197 reads (8%) | called by muse, mutect2
- NHS | c.2118C>A p.H706Q | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.796); called by muse, mutect2
- NOS2 | c.880G>T p.G294C | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NOX4 | c.96A>T p.K32N | Missense Mutation (SNP) | VAF 28/494 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.009); called by muse, mutect2
- NPSR1 | c.588G>T p.Q196H | Missense Mutation (SNP) | VAF 44/564 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- NRP1 | c.589G>C p.D197H | Missense Mutation (SNP) | VAF 34/384 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NRXN3 | c.3011A>T p.N1004I (on ENST00000335750 / NM_001330195.2; = p.N631I on NM_004796.6) | Missense Mutation (SNP) | VAF 22/197 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NUDT11 | c.145G>T p.G49C | Missense Mutation (SNP) | VAF 5/111 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NUFIP2 | c.2000A>C p.K667T | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2
- OCA2 | c.2288T>A p.L763Q | Missense Mutation (SNP) | VAF 23/516 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- OGDHL | c.122C>A p.P41Q | Missense Mutation (SNP) | VAF 14/235 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.014); called by muse, mutect2
- OR1C1 | c.676C>A p.L226M | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.98); called by muse, mutect2
- OR2C3 | c.274A>T p.T92S | Missense Mutation (SNP) | VAF 40/395 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.062); called by muse, mutect2
- OR2T4 | c.18G>T p.W6C | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR52E8 | c.348G>T p.M116I | Missense Mutation (SNP) | VAF 26/313 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.049); called by muse, mutect2
- OR52L1 | c.629C>T p.T210I | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated (0.69); PolyPhen benign (0.105); called by muse, mutect2
- OR8B8 | c.808C>A p.Q270K | Missense Mutation (SNP) | VAF 43/388 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.107); called by muse, varscan2
- OSTM1 | c.452G>T p.R151I | Missense Mutation (SNP) | VAF 20/370 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- PALLD | c.85G>T p.G29C | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); called by muse, mutect2
- PAX2 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 34/553 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.029); called by muse, mutect2
- PCDHB4 | c.304G>T p.V102L | Missense Mutation (SNP) | VAF 20/444 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.107); called by muse, mutect2
- PCDHB9 | c.318C>A p.F106L | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- PCDHB9 | c.322del p.I108Ffs*2 | Frame Shift Del (DEL) | VAF 10/80 reads (13%) | called by mutect2, varscan2
- PCDHGA10 | c.1683C>A p.D561E | Missense Mutation (SNP) | VAF 42/383 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHGB2 | c.985G>A p.A329T | Missense Mutation (SNP) | VAF 17/405 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0.086); called by muse, mutect2
- PDZD2 | c.4681G>C p.D1561H | Missense Mutation (SNP) | VAF 19/281 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); called by muse, mutect2
- PIWIL1 | c.1934C>A p.A645E | Missense Mutation (SNP) | VAF 24/239 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PKD2 | c.2772G>C p.Q924H | Missense Mutation (SNP) | VAF 56/545 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- POF1B | c.811C>A p.L271I | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.724); called by muse, mutect2
- POLQ | c.5665G>C p.G1889R | Missense Mutation (SNP) | VAF 32/265 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- POTEA | c.1317G>T p.E439D (on ENST00000519951 / NM_001005365.2; = p.E393D on NM_001002920.1) | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); called by muse, mutect2
- PRKCG | c.1431C>G p.I477M | Missense Mutation (SNP) | VAF 42/618 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- PRRT3 | c.1999C>A p.R667S | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- RASGEF1C | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 43/373 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- RCSD1 | c.534G>T p.Q178H | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RELN | c.9070C>A p.P3024T | Missense Mutation (SNP) | VAF 56/564 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- RIMS1 | c.2344G>T p.V782L | Missense Mutation (SNP) | VAF 16/350 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- RIT2 | c.267G>T p.M89I | Missense Mutation (SNP) | VAF 12/169 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2
- RPS6KA2 | c.908G>T p.G303V | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- RPTN | c.1483C>A p.Q495K | Missense Mutation (SNP) | VAF 36/322 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- RREB1 | c.80T>C p.V27A | Missense Mutation (SNP) | VAF 37/390 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RSPO2 | c.246C>A p.Y82* | Nonsense Mutation (SNP) | VAF 38/356 reads (11%) | called by muse, mutect2
- RTP4 | c.715G>T p.V239L | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- RYR2 | c.11255G>C p.G3752A | Missense Mutation (SNP) | VAF 29/257 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- SC5D | c.697C>T p.H233Y | Missense Mutation (SNP) | VAF 57/418 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCGN | c.746T>A p.L249H | Missense Mutation (SNP) | VAF 9/184 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SCLT1 | c.809A>T p.E270V | Missense Mutation (SNP) | VAF 34/514 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SDK2 | c.4318C>A p.R1440S | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.778); called by muse, mutect2
- SEMA4A | c.811-8G>T | Splice Region (SNP) | VAF 20/135 reads (15%) | called by muse, mutect2, varscan2
- SERPINE3 | c.338G>A p.C113Y | Missense Mutation (SNP) | VAF 44/500 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- SH2B1 | c.854C>A p.P285H | Missense Mutation (SNP) | VAF 28/298 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.888); called by muse, mutect2
- SIRPG | c.671T>A p.V224D | Missense Mutation (SNP) | VAF 47/310 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC10A2 | c.208G>T p.V70F | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.141); called by muse, mutect2
- SLC15A3 | c.1493T>A p.I498N | Missense Mutation (SNP) | VAF 24/296 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- SLC22A24 | c.962G>T p.R321I | Missense Mutation (SNP) | VAF 12/151 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by muse, mutect2
- SLC30A3 | c.743G>A p.G248E | Missense Mutation (SNP) | VAF 25/420 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLC35F5 | c.467T>C p.M156T | Missense Mutation (SNP) | VAF 16/318 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.005); called by muse, mutect2
- SLC3A1 | c.1507C>A p.L503I | Missense Mutation (SNP) | VAF 24/469 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.035); called by muse, mutect2
- SLC6A18 | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.21); called by muse, mutect2
- SLITRK4 | c.2239G>T p.D747Y | Missense Mutation (SNP) | VAF 27/336 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.229); called by muse, mutect2
- SMCHD1 | c.1708T>G p.Y570D | Missense Mutation (SNP) | VAF 18/367 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.157); called by muse, mutect2
- SMG1 | c.2593G>C p.V865L | Missense Mutation (SNP) | VAF 18/440 reads (4%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2
- SOX9 | c.779C>A p.P260Q | Missense Mutation (SNP) | VAF 29/239 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- SP140 | c.1822C>T p.Q608* | Nonsense Mutation (SNP) | VAF 12/186 reads (6%) | called by muse, mutect2
- SPTA1 | c.5624T>A p.V1875E | Missense Mutation (SNP) | VAF 52/538 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SRD5A1 | c.615G>T p.E205D | Missense Mutation (SNP) | VAF 48/342 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- STMN2 | c.241C>G p.L81V | Missense Mutation (SNP) | VAF 31/309 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- STOML1 | c.1147G>T p.D383Y | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TAOK3 | c.874A>T p.R292W | Missense Mutation (SNP) | VAF 27/239 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TBL1X | c.284T>A p.V95E | Missense Mutation (SNP) | VAF 17/393 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2
- TCF23 | c.173C>G p.A58G | Missense Mutation (SNP) | VAF 13/280 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.055); called by muse, mutect2
- TCOF1 | c.378+8G>T | Splice Region (SNP) | VAF 24/171 reads (14%) | called by muse, mutect2, varscan2
- TEKT1 | c.920A>G p.E307G | Missense Mutation (SNP) | VAF 21/196 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); called by muse, mutect2
- TEX33 | c.489G>T p.Q163H (on ENST00000381821 / NM_001163857.2; = p.Q78H on NM_178552.4) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- THEGL | c.723G>T p.R241S | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- TMEM132C | c.67G>T p.G23C | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.02); called by muse, mutect2, varscan2
- TNFSF9 | c.628C>A p.Q210K | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- TNIK | c.2501A>G p.E834G | Missense Mutation (SNP) | VAF 18/245 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); called by muse, mutect2
- TRDN | c.1699G>T p.A567S | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.011); called by muse, mutect2
- TSSK1B | c.547G>T p.A183S | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.774); called by muse, mutect2
- UBA5 | c.638C>G p.S213* | Nonsense Mutation (SNP) | VAF 26/409 reads (6%) | called by muse, mutect2
- UBL7 | c.7C>G p.L3V | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2
- VIP | c.413G>T p.R138I | Missense Mutation (SNP) | VAF 13/293 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- WDR36 | c.1248G>T p.K416N | Missense Mutation (SNP) | VAF 45/573 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- WDR72 | c.503T>C p.M168T | Missense Mutation (SNP) | VAF 18/234 reads (8%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2
- WDR87 | c.6416T>A p.L2139Q | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WNK4 | c.2006G>C p.R669P | Missense Mutation (SNP) | VAF 45/459 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2
- XKR6 | c.1114G>C p.V372L | Missense Mutation (SNP) | VAF 22/286 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.484); called by muse, mutect2
- XRN1 | c.474C>G p.D158E | Missense Mutation (SNP) | VAF 28/292 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZFHX4 | c.5649A>T p.K1883N | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- ZFPM2 | c.533G>T p.G178V | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF107 | c.1164A>T p.E388D | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.046); called by muse, mutect2
- ZNF350 | c.521C>A p.T174N | Missense Mutation (SNP) | VAF 24/433 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.386); called by muse, mutect2
- ZNF469 | c.9229G>T p.G3077C (on ENST00000437464; = p.G3105C on NM_001367624.2) | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- ZNF582 | c.544C>G p.Q182E | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.037); called by muse, mutect2
- ZNF583 | c.160G>A p.V54M | Missense Mutation (SNP) | VAF 26/452 reads (6%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF735 | c.439C>A p.Q147K | Missense Mutation (SNP) | VAF 28/308 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.93); called by muse, mutect2
- ZNF800 | c.1906C>T p.H636Y | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- AC127029.3 | c.547A>C p.R183= | Silent (SNP) | VAF 22/286 reads (8%) | catalogued as rs200498241; called by muse, mutect2
- AFF1 | c.1917C>G p.S639= | Silent (SNP) | VAF 15/120 reads (13%) | catalogued as COSV57122179; called by muse, mutect2, varscan2
- ANKRD35 | c.2625C>A p.A875= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as rs1553738805; called by muse, mutect2, varscan2
- AQP12A | c.321G>T p.G107= | Silent (SNP) | VAF 9/151 reads (6%) | called by muse, mutect2
- ASB2 | c.225C>A p.T75= | Silent (SNP) | VAF 26/306 reads (8%) | called by muse, mutect2
- ATP13A4 | c.3579A>G p.E1193= | Silent (SNP) | VAF 17/281 reads (6%) | called by muse, mutect2
- B3GNT6 | c.654G>T p.L218= | Silent (SNP) | VAF 13/108 reads (12%) | called by muse, mutect2, varscan2
- BHMT2 | c.1047T>A p.A349= | Silent (SNP) | VAF 35/287 reads (12%) | called by muse, mutect2, varscan2
- C11orf87 | c.240C>A p.S80= | Silent (SNP) | VAF 30/376 reads (8%) | called by muse, mutect2
- CABLES2 | c.969C>A p.I323= | Silent (SNP) | VAF 10/177 reads (6%) | called by muse, mutect2
- CACNA1B | c.2121C>T p.I707= | Silent (SNP) | VAF 16/119 reads (13%) | catalogued as rs367634961; called by muse, mutect2, varscan2
- CACNA1B | c.3408C>A p.T1136= | Silent (SNP) | VAF 20/98 reads (20%) | catalogued as rs1361162992; called by muse, mutect2, varscan2
- CCDC112 | c.480A>T p.T160= | Silent (SNP) | VAF 13/266 reads (5%) | called by muse, mutect2
- CCDC178 | c.2520G>T p.V840= (on ENST00000383096 / NM_001105528.3; = p.V802= on NM_198995.3) | Silent (SNP) | VAF 7/131 reads (5%) | catalogued as COSV55793559; called by muse, mutect2
- CCDC87 | c.2205G>T p.L735= | Silent (SNP) | VAF 23/239 reads (10%) | called by muse, mutect2
- CCER1 | c.444C>T p.R148= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV62646982; called by mutect2, varscan2
- CDH12 | c.136C>A p.R46= | Silent (SNP) | VAF 30/452 reads (7%) | called by muse, mutect2
- CDH7 | c.1350C>A p.I450= | Silent (SNP) | VAF 20/224 reads (9%) | called by muse, mutect2
- CHMP1A | c.366G>T p.L122= | Silent (SNP) | VAF 24/202 reads (12%) | called by muse, mutect2, varscan2
- CLCA1 | c.1005G>A p.L335= | Silent (SNP) | VAF 22/293 reads (8%) | catalogued as rs1437705774; called by muse, mutect2
- CLNK | c.912C>G p.V304= | Silent (SNP) | VAF 10/240 reads (4%) | called by muse, mutect2
- CP | c.1926C>A p.V642= | Silent (SNP) | VAF 57/471 reads (12%) | called by muse, mutect2, varscan2
- CYFIP1 | c.1758G>T p.G586= | Silent (SNP) | VAF 24/206 reads (12%) | called by muse, mutect2
- DAAM2 | c.2022T>C p.D674= | Silent (SNP) | VAF 15/304 reads (5%) | called by muse, mutect2
- DGKB | c.1764C>T p.S588= | Silent (SNP) | VAF 8/128 reads (6%) | catalogued as COSV99338743; called by muse, mutect2
- DMBX1 | c.918C>A p.G306= | Silent (SNP) | VAF 21/136 reads (15%) | catalogued as COSV100760910; called by muse, mutect2, varscan2
- DMD | c.9444G>T p.L3148= | Silent (SNP) | VAF 27/716 reads (4%) | catalogued as COSV58959967; called by muse, mutect2
- DNAH14 | c.6291T>C p.F2097= (on ENST00000445597; = p.F2750= on NM_001367479.1) | Silent (SNP) | VAF 31/288 reads (11%) | called by muse, mutect2, varscan2
- DUSP22 | c.297G>T p.V99= | Silent (SNP) | VAF 26/348 reads (7%) | catalogued as COSV60523552; called by muse, mutect2
- DYSF | c.4914T>A p.P1638= | Silent (SNP) | VAF 57/507 reads (11%) | called by muse, mutect2, varscan2
- FAM120C | c.552C>A p.G184= | Silent (SNP) | VAF 11/277 reads (4%) | called by muse, mutect2
- FAM181A | c.354G>T p.P118= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs764387512, COSV50888302; called by muse, mutect2
- FBN2 | c.3870T>C p.N1290= | Silent (SNP) | VAF 38/524 reads (7%) | catalogued as COSV52547147; called by muse, mutect2
- FBXO24 | c.610T>C p.L204= (on ENST00000241071 / NM_033506.3; = p.L242= on NM_012172.5) | Silent (SNP) | VAF 15/248 reads (6%) | called by muse, mutect2
- FUT5 | c.469C>A p.R157= | Silent (SNP) | VAF 38/238 reads (16%) | called by muse, mutect2, varscan2
- GABRA5 | c.847C>A p.R283= | Silent (SNP) | VAF 10/128 reads (8%) | catalogued as COSV59481451; called by muse, mutect2
- GAP43 | c.678T>A p.G226= | Silent (SNP) | VAF 14/268 reads (5%) | called by muse, mutect2
- GBP4 | c.201C>A p.S67= | Silent (SNP) | VAF 14/121 reads (12%) | called by muse, mutect2
- GPRC5B | c.531T>A p.A177= | Silent (SNP) | VAF 13/111 reads (12%) | called by muse, mutect2, varscan2
- H2BC13 | c.240C>A p.R80= | Silent (SNP) | VAF 33/426 reads (8%) | called by muse, mutect2
- H3-5 | c.138G>T p.V46= | Silent (SNP) | VAF 43/399 reads (11%) | called by muse, mutect2, varscan2
- HDGFL1 | c.6G>A p.S2= | Silent (SNP) | VAF 10/86 reads (12%) | called by muse, mutect2, varscan2
- HTR3A | c.1332C>A p.R444= | Silent (SNP) | VAF 31/198 reads (16%) | catalogued as rs766338857, COSV55469643; called by muse, mutect2, varscan2
- HYKK | c.354C>A p.I118= | Silent (SNP) | VAF 16/147 reads (11%) | called by muse, mutect2, varscan2
- ITGAD | c.645G>T p.V215= | Silent (SNP) | VAF 34/308 reads (11%) | called by muse, mutect2, varscan2
- KCNH7 | c.3525C>A p.S1175= | Silent (SNP) | VAF 9/196 reads (5%) | called by muse, mutect2
- KLF7 | c.666G>A p.Q222= | Silent (SNP) | VAF 19/180 reads (11%) | called by muse, mutect2, varscan2
- LARGE1 | c.1974G>A p.E658= | Silent (SNP) | VAF 28/422 reads (7%) | called by muse, mutect2
- LRFN2 | c.2244C>A p.V748= | Silent (SNP) | VAF 10/134 reads (7%) | called by muse, mutect2
- MAGEB5 | c.405T>A p.T135= | Silent (SNP) | VAF 9/141 reads (6%) | called by muse, mutect2
- MAP3K15 | c.2436C>A p.T812= | Silent (SNP) | VAF 15/370 reads (4%) | called by muse, mutect2
- MCM6 | c.1098G>T p.R366= | Silent (SNP) | VAF 14/166 reads (8%) | called by muse, mutect2
- MED12L | c.6363G>C p.R2121= | Silent (SNP) | VAF 24/202 reads (12%) | called by muse, varscan2
- MOXD1 | c.1536C>A p.P512= | Silent (SNP) | VAF 10/127 reads (8%) | catalogued as rs1205666661; called by muse, mutect2
- MYO9B | c.4017G>T p.R1339= | Silent (SNP) | VAF 32/253 reads (13%) | called by muse, mutect2, varscan2
- NGLY1 | c.189T>C p.T63= | Silent (SNP) | VAF 38/259 reads (15%) | called by muse, mutect2, varscan2
- OPRL1 | c.1071C>T p.A357= | Silent (SNP) | VAF 9/54 reads (17%) | called by muse, mutect2, varscan2
- OR2L13 | c.846C>G p.P282= | Silent (SNP) | VAF 27/265 reads (10%) | called by muse, mutect2, varscan2
- OR5F1 | c.801C>A p.S267= | Silent (SNP) | VAF 12/187 reads (6%) | catalogued as COSV99558443, COSV99558733; called by muse, mutect2
- OR8I2 | c.411C>A p.S137= | Silent (SNP) | VAF 26/185 reads (14%) | catalogued as COSV100135774, COSV100136036; called by muse, mutect2, varscan2
- OSBPL10 | c.951G>A p.L317= | Silent (SNP) | VAF 28/297 reads (9%) | catalogued as rs764449060; called by muse, mutect2
- OTOG | c.894C>G p.T298= | Silent (SNP) | VAF 20/104 reads (19%) | called by muse, mutect2, varscan2
- PAQR9 | c.789C>A p.L263= | Silent (SNP) | VAF 18/166 reads (11%) | called by muse, mutect2, varscan2
- PCDHA12 | c.1710T>A p.A570= | Silent (SNP) | VAF 22/458 reads (5%) | called by muse, mutect2
- PCDHA7 | c.1257C>T p.S419= | Silent (SNP) | VAF 20/354 reads (6%) | catalogued as rs782760321, COSV65345716; called by muse, mutect2
- PCDHB2 | c.852C>A p.S284= | Silent (SNP) | VAF 19/208 reads (9%) | called by muse, mutect2
- PCDHB7 | c.513C>A p.T171= | Silent (SNP) | VAF 6/83 reads (7%) | called by muse, mutect2
- PSG6 | c.981C>A p.V327= | Silent (SNP) | VAF 15/87 reads (17%) | called by muse, mutect2, varscan2
- PTPN5 | c.1557G>A p.E519= | Silent (SNP) | VAF 16/170 reads (9%) | called by muse, mutect2
- PTPRU | c.3456C>T p.I1152= | Silent (SNP) | VAF 27/218 reads (12%) | catalogued as COSV100111330; called by muse, mutect2, varscan2
- RBM10 | c.2247G>T p.R749= | Silent (SNP) | VAF 8/177 reads (5%) | called by muse, mutect2
- REXO1 | c.3243G>T p.V1081= | Silent (SNP) | VAF 23/149 reads (15%) | called by muse, mutect2, varscan2
- SCAF8 | c.2082G>T p.P694= | Silent (SNP) | VAF 29/559 reads (5%) | called by muse, mutect2
- SCN2A | c.5430C>G p.T1810= | Silent (SNP) | VAF 39/447 reads (9%) | called by muse, mutect2
- SERPINE1 | c.72G>C p.V24= | Silent (SNP) | VAF 12/133 reads (9%) | catalogued as COSV56169781; called by muse, mutect2
- SF3A1 | c.1692C>T p.T564= | Silent (SNP) | VAF 34/418 reads (8%) | called by muse, mutect2
- SH3PXD2A | c.1572G>T p.P524= (on ENST00000369774 / NM_001365079.1; = p.P496= on NM_014631.2) | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs551796306, COSV100279914; called by mutect2, varscan2
- SIDT2 | c.1395G>C p.V465= | Silent (SNP) | VAF 42/275 reads (15%) | called by muse, mutect2, varscan2
- SLC7A13 | c.138G>T p.V46= | Silent (SNP) | VAF 22/270 reads (8%) | called by muse, mutect2
- SLFN11 | c.882C>T p.T294= | Silent (SNP) | VAF 12/126 reads (10%) | called by muse, mutect2
- SPTBN4 | c.1827C>A p.P609= | Silent (SNP) | VAF 9/67 reads (13%) | called by muse, mutect2, varscan2
- SVEP1 | c.7059T>C p.H2353= | Silent (SNP) | VAF 14/273 reads (5%) | called by muse, mutect2
- TAS1R3 | c.699C>A p.R233= | Silent (SNP) | VAF 9/64 reads (14%) | called by muse, mutect2, varscan2
- TEX37 | c.354G>T p.L118= | Silent (SNP) | VAF 42/356 reads (12%) | called by muse, mutect2, varscan2
- TMEM204 | c.213T>C p.H71= | Silent (SNP) | VAF 21/181 reads (12%) | called by muse, mutect2, varscan2
- TRPC7 | c.1443C>T p.I481= | Silent (SNP) | VAF 52/458 reads (11%) | called by muse, mutect2, varscan2
- UNC5A | c.576G>A p.P192= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs199618550, COSV99995298; called by muse, mutect2
- UNC80 | c.1875C>T p.S625= | Silent (SNP) | VAF 20/460 reads (4%) | called by muse, mutect2
- ZC3H10 | c.105G>T p.G35= | Silent (SNP) | VAF 10/67 reads (15%) | called by muse, mutect2, varscan2
- ZFP57 | c.1062G>T p.V354= | Silent (SNP) | VAF 54/674 reads (8%) | called by muse, mutect2
- ZNF524 | c.99C>T p.G33= | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as rs1013504239; called by muse, mutect2, varscan2
- ZP2 | c.1818G>T p.V606= | Silent (SNP) | VAF 12/127 reads (9%) | called by muse, mutect2
- ABCD1 | c.1081+36G>T | Intron (SNP) | VAF 15/90 reads (17%) | called by muse, mutect2, varscan2
- AC022364.1 | chr12:28183755 C>A | 3'Flank (SNP) | VAF 33/414 reads (8%) | called by muse, mutect2
- AC024940.1 | n.2241C>A | RNA (SNP) | VAF 37/197 reads (19%) | called by muse, mutect2, varscan2
- AC048338.2 | c.*152G>T | 3'UTR (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- AC139491.1 | n.562G>T | RNA (SNP) | VAF 8/120 reads (7%) | called by muse, varscan2
- AC244258.1 | n.982G>T | RNA (SNP) | VAF 20/266 reads (8%) | called by muse, mutect2
- AC244517.10 | c.36-9972G>T | Intron (SNP) | VAF 12/260 reads (5%) | called by muse, mutect2
- ACTG1P17 | n.758G>T | RNA (SNP) | VAF 11/118 reads (9%) | called by muse, mutect2
- AKAP6 | c.*110G>A | 3'UTR (SNP) | VAF 22/422 reads (5%) | catalogued as rs930566183, COSV55226239; called by muse, mutect2
- ARHGAP23P1 | chr16:33938421 G>T | 5'Flank (SNP) | VAF 12/194 reads (6%) | called by muse, mutect2
- C19orf12 | chr19:29702395 G>A | 3'Flank (SNP) | VAF 48/476 reads (10%) | catalogued as rs761763218; called by muse, mutect2, varscan2
- CACNB4 | c.699+264T>C | Intron (SNP) | VAF 20/212 reads (9%) | called by muse, mutect2
- CEP126 | c.507-1594G>A | Intron (SNP) | VAF 36/297 reads (12%) | called by muse, mutect2, varscan2
- CEROX1 | n.2897G>T | RNA (SNP) | VAF 32/389 reads (8%) | called by muse, mutect2
- CHRNA4 | c.*3231G>T | 3'UTR (SNP) | VAF 12/291 reads (4%) | called by muse, mutect2
- CYP11B2 | c.954+235G>T | Intron (SNP) | VAF 18/159 reads (11%) | called by muse, mutect2, varscan2
- DPP6 | c.457+69G>T | Intron (SNP) | VAF 19/263 reads (7%) | called by muse, mutect2
- ERC1 | c.2487+7667G>T | Intron (SNP) | VAF 34/246 reads (14%) | called by muse, mutect2, varscan2
- EYS | c.749-826G>T | Intron (SNP) | VAF 11/150 reads (7%) | called by muse, mutect2
- FHL2 | chr2:105399288 C>A | 5'Flank (SNP) | VAF 19/175 reads (11%) | catalogued as rs1378513681; called by muse, mutect2, varscan2
- FIP1L1 | c.1175-1959G>T | Intron (SNP) | VAF 8/178 reads (4%) | catalogued as rs1024754637; called by muse, mutect2
- FLNB | c.7417+33C>T | Intron (SNP) | VAF 25/224 reads (11%) | called by muse, mutect2, varscan2
- GBA3 | c.59-8475G>T | Intron (SNP) | VAF 38/506 reads (8%) | catalogued as rs1553846449; called by muse, mutect2
- GORAB | c.*413G>T | 3'UTR (SNP) | VAF 18/164 reads (11%) | catalogued as rs1393340143; called by muse, mutect2, varscan2
- HOXB3 | c.-232C>G | 5'UTR (SNP) | VAF 34/388 reads (9%) | called by muse, mutect2
- HSD17B10 | c.*39C>G | 3'UTR (SNP) | VAF 11/171 reads (6%) | called by muse, mutect2
- LDB2 | c.892-186C>G | Intron (SNP) | VAF 9/175 reads (5%) | called by muse, mutect2
- LINC01036 | n.155G>T | RNA (SNP) | VAF 24/126 reads (19%) | called by muse, mutect2
- LINC01956 | n.297C>G | RNA (SNP) | VAF 17/255 reads (7%) | called by muse, mutect2
- MYO7B | c.6250-55G>A | Intron (SNP) | VAF 6/70 reads (9%) | catalogued as rs1380567354; called by muse, mutect2
- NAMPTP1 | n.857A>C | RNA (SNP) | VAF 44/504 reads (9%) | called by muse, mutect2
- NBPF22P | n.1158G>T | RNA (SNP) | VAF 18/382 reads (5%) | called by muse, mutect2
- OR2M1P | n.499T>C | RNA (SNP) | VAF 17/344 reads (5%) | called by muse, mutect2
- PHGDH | c.356+1470G>T | Intron (SNP) | VAF 89/450 reads (20%) | called by muse, mutect2, varscan2
- PPDPFL | c.*604C>T | 3'UTR (SNP) | VAF 33/374 reads (9%) | catalogued as rs761846182; called by muse, mutect2
- PRRT1 | chr6:32152104 C>T | 5'Flank (SNP) | VAF 40/445 reads (9%) | catalogued as rs1044948087, COSV99278656; called by muse, mutect2
- PTGER3 | c.*11G>T | 3'UTR (SNP) | VAF 14/192 reads (7%) | catalogued as COSV100139920; called by muse, mutect2
- RNF112 | c.-6C>A | 5'UTR (SNP) | VAF 10/170 reads (6%) | called by muse, mutect2
- RNF217-AS1 | n.2159C>A | RNA (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
- SLC15A1 | c.556+162G>T | Intron (SNP) | VAF 50/371 reads (13%) | called by muse, mutect2, varscan2
- SLC25A28 | c.520+21G>C | Intron (SNP) | VAF 16/295 reads (5%) | called by muse, mutect2
- SMG1 | c.3954-22G>T | Intron (SNP) | VAF 20/211 reads (9%) | called by muse, mutect2, varscan2
- SPATA31C2 | n.1968C>A | RNA (SNP) | VAF 49/502 reads (10%) | called by muse, mutect2, varscan2
- STK19 | c.567+128G>T | Intron (SNP) | VAF 44/357 reads (12%) | called by muse, mutect2, varscan2
- SV2C | c.581-21139G>T | Intron (SNP) | VAF 44/603 reads (7%) | catalogued as COSV59213064; called by muse, mutect2
- TBX2 | chr17:61412574 G>C | 3'Flank (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- TBX3 | c.*48T>A | 3'UTR (SNP) | VAF 27/241 reads (11%) | called by muse, mutect2, varscan2
- TEX35 | c.217-11T>A | Intron (SNP) | VAF 15/122 reads (12%) | called by muse, mutect2, varscan2
- TFDP1 | c.1007-132G>T | Intron (SNP) | VAF 37/343 reads (11%) | called by muse, mutect2, varscan2
- TGFBR3 | c.*1678G>T | 3'UTR (SNP) | VAF 23/294 reads (8%) | called by muse, mutect2
- TRPC6 | c.1128+43G>T | Intron (SNP) | VAF 23/223 reads (10%) | called by muse, mutect2, varscan2
- TWF1 | c.25+695C>T | Intron (SNP) | VAF 26/145 reads (18%) | called by muse, mutect2, varscan2
- TXNRD1 | c.-17A>T | 5'UTR (SNP) | VAF 26/212 reads (12%) | called by muse, mutect2, varscan2
- UBN2 | c.2024+39C>T | Intron (SNP) | VAF 16/248 reads (6%) | called by muse, mutect2
- WWP2 | c.1683-837A>G | Intron (SNP) | VAF 14/134 reads (10%) | catalogued as rs1477409800; called by muse, mutect2
- ZEB2 | c.73+3720C>A | Intron (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2, varscan2
